Somatic mutation profile of tumor specimen C3N-03029-01 (aliquot CPT0244570009) from CPTAC case C3N-03029, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.3 years (25,692 days).
Specimen C3N-03029-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86cfc31c-e979-4ee2-805a-53532254b28b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03029-31 (Blood Derived Normal), aliquot CPT0244590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dc8bb34-9051-41e8-9dac-46060ad9bf45

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 2, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- A4GALT | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 32/816 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1166307243, COSV50744566; called by muse, mutect2
- C10orf71 | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV60513909; called by muse, mutect2
- CETN1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs768969475, COSV59121657; called by muse, mutect2, varscan2
- GRID1 | c.2233G>A p.V745M | Missense Mutation (SNP) | VAF 42/457 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs747770345, COSV60044244; called by muse, mutect2
- KRT85 | c.1057A>T p.I353F | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57738551; called by muse, mutect2, varscan2
- PCDHGB5 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53908456; called by muse, mutect2
- ZAN | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs1194056805; called by muse, mutect2, varscan2
- ARHGAP23 | c.4213_4226del p.R1405Gfs*7 | Frame Shift Del (DEL) | VAF 44/414 reads (11%) | called by mutect2, pindel
- CDH17 | c.117T>G p.Y39* | Nonsense Mutation (SNP) | VAF 36/371 reads (10%) | called by muse, mutect2
- CDON | c.3296C>A p.A1099D | Missense Mutation (SNP) | VAF 68/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CSF2RB | c.1153-1G>A p.X385_splice | Splice Site (SNP) | VAF 30/344 reads (9%) | called by muse, mutect2
- EGF | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- ENTPD2 | c.1083dup p.P362Afs*277 (on ENST00000355097 / NM_203468.3; = p.P362Afs*? on NM_001246.4) | Frame Shift Ins (INS) | VAF 30/319 reads (9%) | called by mutect2, pindel
- EXPH5 | c.1338_1339del p.N447Hfs*45 | Frame Shift Del (DEL) | VAF 53/394 reads (13%) | called by pindel, varscan2
- FBLN2 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 50/434 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.158); called by mutect2, varscan2
- HSPA12B | c.1456G>C p.V486L | Missense Mutation (SNP) | VAF 62/691 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LHX2 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 28/750 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRC23 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 15/360 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); called by muse, mutect2
- NOL8 | c.1442G>A p.C481Y | Missense Mutation (SNP) | VAF 26/345 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR1C1 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 33/582 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- OR4E2 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- PNPLA7 | c.3839A>G p.Q1280R | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- SNTG2 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 31/465 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- SOWAHC | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 33/339 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- UTP20 | c.2845G>C p.D949H | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2
- ZEB2 | c.917-8C>T | Splice Region (SNP) | VAF 35/446 reads (8%) | called by muse, mutect2
- GPRC6A | c.1794G>C p.L598= | Silent (SNP) | VAF 40/478 reads (8%) | called by muse, mutect2
- HEATR1 | c.4762T>C p.L1588= | Silent (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- LRRC70 | c.1102T>C p.L368= | Silent (SNP) | VAF 33/399 reads (8%) | catalogued as rs997408195; called by muse, mutect2
- MFSD8 | c.1080A>G p.Q360= | Silent (SNP) | VAF 34/346 reads (10%) | catalogued as rs751316775; called by muse, mutect2
- MYO15B | c.3792C>T p.F1264= | Silent (SNP) | VAF 38/410 reads (9%) | catalogued as COSV101646230; called by muse, mutect2
- MYO18B | c.4485G>A p.L1495= | Silent (SNP) | VAF 28/343 reads (8%) | catalogued as rs1451461597; called by muse, mutect2
- SYN2 | c.1227A>G p.L409= | Silent (SNP) | VAF 33/476 reads (7%) | called by muse, mutect2
- ZFPM2 | c.2092C>A p.R698= | Silent (SNP) | VAF 31/398 reads (8%) | catalogued as rs375403029, COSV101022963; called by muse, mutect2
- SHISA8 | chr22:41909864 C>T | 3'Flank (SNP) | VAF 66/1080 reads (6%) | called by muse, mutect2
